Somatic mutation profile of tumor specimen TCGA-AA-3679-01A (aliquot TCGA-AA-3679-01A-02W-0900-09) from TCGA case TCGA-AA-3679, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 59.2 years (21,611 days).
Specimen TCGA-AA-3679-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21bfc2db-d749-40e2-9f04-d2bdce89583c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3679-10A (Blood Derived Normal), aliquot TCGA-AA-3679-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/962bc464-5511-4ad2-82fa-1d9e40535ff6

The open-access MAF lists 79 somatic variants for this specimen: 56 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 20, Nonsense Mutation 5, Intron 3, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 43/101 reads (43%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 22/39 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as rs780201945, COSV55781637; called by muse, mutect2, varscan2
- ADGRB3 | c.2698G>T p.A900S | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV53250306; called by muse, mutect2, varscan2
- ANO6 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV57663254; called by muse, mutect2, varscan2
- ARHGDIB | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56763854; called by muse, mutect2, varscan2
- ATM | c.1495C>G p.Q499E | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV53752784, COSV99586825; called by muse, mutect2, varscan2
- BAX | c.417G>T p.W139C | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV53170791; called by muse, mutect2, varscan2
- CBLB | c.2659C>T p.Q887* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV51429898; called by muse, mutect2, varscan2
- CDH11 | c.1639C>G p.R547G | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV51767131, COSV99219998; called by muse, mutect2, varscan2
- CDH3 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200463078, COSV50561248; called by muse, mutect2, varscan2
- CHST4 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201260953, COSV58296510; called by muse, mutect2, varscan2
- DDC | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777956037, CM149259, COSV63565591; called by muse, mutect2
- ELOA2 | c.1346C>A p.A449D | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV55301793; called by muse, mutect2, varscan2
- EXOSC2 | c.123G>T p.R41= | Splice Region (SNP) | VAF 18/63 reads (29%) | catalogued as COSV64910678; called by muse, mutect2, varscan2
- FAM135A | c.1038_1039insG p.F347Vfs*3 (on ENST00000370479 / NM_001351599.1; = p.F330Vfs*3 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 63/288 reads (22%) | catalogued as COSV99525460; called by mutect2, pindel, varscan2
- FBXW8 | c.1358G>A p.R453H (on ENST00000309909; = p.R491H on NM_012174.1) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs368052577; called by muse, mutect2, varscan2
- GABRA5 | c.42C>A p.N14K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV59481648; called by muse, mutect2, varscan2
- GFM1 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99962772; called by muse, mutect2
- IGF2R | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV63630256; called by muse, mutect2
- JPH3 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs569623845, COSV52466972; called by muse, mutect2, varscan2
- KCNK17 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376144090, COSV64685964; called by muse, mutect2, varscan2
- LHFPL6 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 103/319 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as rs769854247, COSV65446977; called by muse, mutect2, varscan2
- MAST2 | c.3080G>A p.R1027H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs772193704, COSV63616701; called by muse, mutect2, varscan2
- MFHAS1 | c.2756A>G p.Y919C | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs780991918, COSV52283808; called by muse, mutect2, varscan2
- MRGPRX1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs531949208, COSV57106494; called by muse, mutect2, varscan2
- MTSS1 | c.2144G>A p.S715N | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52675386; called by muse, mutect2, varscan2
- NIT2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373969032; called by muse, mutect2, varscan2
- NOTCH4 | c.1817A>G p.D606G | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100900494; called by muse, mutect2
- OR4D9 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as COSV61434924; called by muse, mutect2, varscan2
- PCDH9 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 184/267 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60563374; called by muse, mutect2, varscan2
- PCNX4 | c.1320G>T p.M440I (on ENST00000406854 / NM_001330177.2; = p.M206I on NM_022495.5) | Missense Mutation (SNP) | VAF 106/235 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV58305430; called by muse, mutect2, varscan2
- PHF24 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.409); catalogued as rs557271865, COSV54275141; called by muse, mutect2, varscan2
- PI4KA | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs200824315, COSV55414706; called by muse, mutect2, varscan2
- PRKAG1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60291524; called by muse, mutect2, varscan2
- PSG4 | c.1116T>G p.F372L | Missense Mutation (SNP) | VAF 125/346 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.867); catalogued as COSV54936885; called by muse, mutect2, varscan2
- REG3A | c.148C>A p.H50N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100532643, COSV100532800, COSV59408769; called by muse, mutect2, varscan2
- ROBO1 | c.915C>A p.S305= | Splice Region (SNP) | VAF 7/184 reads (4%) | catalogued as rs1366916355, COSV71393002; called by muse, mutect2
- SEMA3D | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004792133, COSV52396971; called by muse, mutect2, varscan2
- STIP1 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV54181066; called by muse, mutect2, varscan2
- STX16 | c.395T>G p.L132R (on ENST00000371141 / NM_001001433.3; = p.L111R on NM_003763.6) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56606770; called by muse, mutect2, varscan2
- STX4 | c.810G>T p.R270S | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV58268721; called by muse, mutect2, varscan2
- SUGP2 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV58261025; called by muse, mutect2, varscan2
- TMEM132B | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.88); catalogued as rs764032288, COSV54748156; called by muse, mutect2
- TPR | c.5887G>A p.E1963K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV66599051, COSV66602432; called by muse, mutect2, varscan2
- TTLL9 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.049); catalogued as COSV60593731; called by muse, mutect2, varscan2
- UGGT2 | c.661-1G>C p.X221_splice | Splice Site (SNP) | VAF 61/322 reads (19%) | catalogued as COSV100942498; called by muse, mutect2, varscan2
- UGP2 | c.301A>C p.I101L | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV61428704; called by muse, mutect2, varscan2
- UNC13C | c.2893C>G p.P965A | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.084); catalogued as COSV52890243; called by muse, mutect2, varscan2
- WIPF1 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 114/200 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.336); catalogued as rs770105478, COSV55816381, COSV55816628; called by muse, mutect2, varscan2
- WSCD2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs754495429, COSV54580610; called by muse, mutect2, varscan2
- ZC3H12C | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs764220083, COSV53710043; called by muse, mutect2, varscan2
- ZNF133 | c.1838G>T p.R613L (on ENST00000316358 / NM_001352454.2; = p.R612L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV100315338; called by muse, mutect2
- ARHGAP31 | c.3595del p.A1199Rfs*106 | Frame Shift Del (DEL) | VAF 54/190 reads (28%) | called by mutect2, pindel, varscan2
- DNAH9 | c.11063_11072del p.I3688Tfs*40 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | called by mutect2, pindel
- MREG | c.420del p.A142Lfs*6 | Frame Shift Del (DEL) | VAF 27/139 reads (19%) | called by mutect2, pindel, varscan2
- DOCK8 | c.3870G>A p.A1290= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs750379098, COSV66621223; called by muse, mutect2, varscan2
- ESR2 | c.772C>T p.L258= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs143949374; called by muse, mutect2, varscan2
- EXOSC10 | c.1227C>G p.L409= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV58666229; called by muse, mutect2, varscan2
- FBXO27 | c.588C>T p.H196= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs753532089, COSV53072612; called by muse, mutect2, varscan2
- H2BC14 | c.204C>T p.N68= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV60798117; called by muse, mutect2, varscan2
- KRT38 | c.726C>T p.H242= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs761707242, COSV55846503; called by muse, mutect2, varscan2
- KYNU | c.1305G>T p.V435= | Silent (SNP) | VAF 102/382 reads (27%) | catalogued as COSV51586146; called by muse, mutect2, varscan2
- LRP1B | c.3834A>G p.R1278= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV67239747; called by muse, mutect2, varscan2
- MB21D2 | c.777T>C p.D259= | Silent (SNP) | VAF 63/121 reads (52%) | catalogued as rs1412913874, COSV66664297; called by muse, mutect2, varscan2
- PCDHGA6 | c.1947C>T p.H649= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs766254447, COSV53893536; called by muse, mutect2, varscan2
- PCYT1A | c.54G>A p.A18= | Silent (SNP) | VAF 283/518 reads (55%) | catalogued as rs200496999, COSV53055859, COSV53058192; called by muse, mutect2, varscan2
- PKN2 | c.1971C>T p.F657= | Silent (SNP) | VAF 110/265 reads (42%) | catalogued as COSV60132594; called by muse, mutect2, varscan2
- POU3F4 | c.60G>A p.A20= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as COSV64539799; called by muse, mutect2, varscan2
- PPFIA3 | c.2205G>A p.A735= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs376973066; called by muse, mutect2, varscan2
- PRKDC | c.10596C>G p.P3532= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV58056328; called by muse, mutect2, varscan2
- PYHIN1 | c.891G>A p.T297= | Silent (SNP) | VAF 38/157 reads (24%) | catalogued as rs781732125, COSV63722960; called by muse, mutect2, varscan2
- RASA3 | c.513G>A p.T171= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs575958394, COSV61868967; called by muse, mutect2, varscan2
- RHBG | c.591G>T p.S197= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs371780489, COSV54806644; called by muse, mutect2, varscan2
- SYTL2 | c.1152T>A p.S384= | Silent (SNP) | VAF 121/316 reads (38%) | catalogued as COSV60360462; called by muse, mutect2, varscan2
- TRAPPC10 | c.723C>T p.D241= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs781551997, COSV52378682; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83417del | Intron (DEL) | VAF 80/248 reads (32%) | catalogued as rs959845413; called by mutect2, pindel, varscan2
- CREM | c.698-5358C>T | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as rs370167560; called by muse, mutect2, varscan2
- NBPF11 | c.-548-2987G>A | Intron (SNP) | VAF 11/48 reads (23%) | catalogued as rs1270467956; called by muse, mutect2, varscan2
